MMRF case MMRF_1049 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d6742460-d3b9-41f0-98be-f117a8d1609c

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.0 years (24,843 days); ISS stage: II; Days to last known disease status: 1,798 days (4.9 years); Days to last follow up: 1,798 days (4.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 49 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 49 days; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 697 days (1.9 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 183 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 1,079 days (3.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 218 days; Days to treatment end: 1,037 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide + Panobinostat; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,084 days (3.0 years); Days to treatment end: 1,240 days (3.4 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,291 days (3.5 years); Days to treatment end: 1,315 days (3.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,392 days (3.8 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,406 days (3.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 0): M Protein 4.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.842 mg/dL; Immunoglobulin G 37.8 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.67 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.78 mmol/L; Albumin 32 g/L; Total Protein 9.8 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 71 (ECOG 1): M Protein 3.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.079 mg/dL; Immunoglobulin G 28.8 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 36 g/L; Total Protein 8.5 g/dL; Glucose 4.73 mmol/L.
- Day 189 (ECOG 0): M Protein 2.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.868 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.047 mg/dL; Immunoglobulin G 20.9 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 37 g/L; Total Protein 7.6 g/dL; Glucose 4.24 mmol/L.
- Day 274: M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.451 mg/dL; Immunoglobulin G 16.6 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.01 ×10⁹/L; Platelets 155 ×10⁹/L.
- Day 351: M Protein 1.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.089 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 4.18 mmol/L.
- Day 434 (ECOG 0): M Protein 0.87 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.099 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.04 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.29 mmol/L.
- Day 546 (ECOG 0): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.937 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.121 mg/dL; Immunoglobulin G 7.18 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 6.2 g/dL; Glucose 4.46 mmol/L.
- Day 658 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.774 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.573 mg/dL; Immunoglobulin G 5.97 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 4.13 mmol/L.
- Day 756 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.715 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.609 mg/dL; Immunoglobulin G 5.66 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.89 mmol/L.
- Day 820 (ECOG 0): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.971 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.627 mg/dL; Immunoglobulin G 6.96 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.29 mmol/L.
- Day 932 (ECOG 0): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.515 mg/dL; Immunoglobulin G 7.18 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 3.91 mmol/L.
- Day 988 (ECOG 0): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.537 mg/dL; Immunoglobulin G 7.84 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 4.18 mmol/L.
- Day 1,079 (ECOG 0): M Protein 1.02 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.797 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.55 mmol/L; Albumin 46 g/L; Total Protein 7.7 g/dL; Glucose 4.24 mmol/L.
- Day 1,169 (ECOG 0): M Protein 1.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.542 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.8 g/dL; Glucose 7.15 mmol/L.
- Day 1,255 (ECOG 0): M Protein 1.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.559 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 5.83 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 4.68 mmol/L.
- Day 1,336 (ECOG 0): M Protein 2.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.134 mg/dL; Immunoglobulin G 23.5 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.24 µg/mL; Hemoglobin 5.83 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 38 g/L; Total Protein 8.4 g/dL; Glucose 4.68 mmol/L.
- Day 1,420 (ECOG 0): M Protein 1.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.169 mg/dL; Immunoglobulin G 17.1 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 5.39 mmol/L.
- Day 1,504 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.992 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.134 mg/dL; Immunoglobulin G 8.07 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 4.62 mmol/L.
- Day 1,616 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 6.73 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 4.46 mmol/L.
- Day 1,700 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.832 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.496 mg/dL; Immunoglobulin G 5.22 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.08 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 4.73 mmol/L.
- Day 1,798 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.571 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.431 mg/dL; Immunoglobulin G 5.31 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day -4: Weight: 75 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (5 samples)
- Sample MMRF_1049_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1049_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
- Sample MMRF_1049_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,079 days (3.0 years).
- Sample MMRF_1049_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,255 days (3.4 years).
- Sample MMRF_1049_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,336 days (3.7 years).
